Somatic mutation profile of tumor specimen 0DSWZ7 from CCDI case PBCIDV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.2 years (2,271 days).
Specimen 0DSWZ7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0954661-f2dc-4c52-9713-0d4b9e54ec0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSWZ0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fa809f79-0a3f-48aa-be36-e98f05a102ed

The open-access MAF lists 19 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 3, 3'UTR 2, RNA 1, Nonstop Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 376/813 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALPK3 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 141/339 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs777370400, COSV51930090; called by muse, varscan2
- LRRC43 | c.239C>T p.T80M | Missense Mutation (SNP) | VAF 231/452 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs753792682, COSV60289071; called by muse, mutect2, varscan2
- OR7A5 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 232/488 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs143093089, COSV100457664, COSV59234008; called by muse, mutect2, varscan2
- SERPINB6 | c.785C>T p.T262M (on ENST00000612421 / NM_001271823.2; = p.T243M on NM_004568.6) | Missense Mutation (SNP) | VAF 213/491 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as rs776896710, COSV59564702; called by muse, mutect2, varscan2
- SMARCA4 | c.3529G>A p.D1177N | Missense Mutation (SNP) | VAF 370/830 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60789707; called by muse, mutect2, varscan2
- TTN | c.45683T>C p.I15228T (on ENST00000591111; = p.I7804T on NM_003319.4) | Missense Mutation (SNP) | VAF 457/1172 reads (39%) | PolyPhen possibly damaging (0.736); catalogued as rs184856328; called by muse, mutect2, varscan2
- DNAH6 | c.3097A>G p.K1033E | Missense Mutation (SNP) | VAF 314/854 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- KIAA1549 | c.4707G>T p.Q1569H | Missense Mutation (SNP) | VAF 72/766 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR5B17 | c.74T>A p.L25H | Missense Mutation (SNP) | VAF 306/738 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ORC5 | c.1306T>A p.*436Rext*14 | Nonstop Mutation (SNP) | VAF 196/657 reads (30%) | called by muse, mutect2, varscan2
- PRPF40A | c.2514G>C p.E838D | Missense Mutation (SNP) | VAF 198/528 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CYP4F11 | c.1335C>T p.F445= | Silent (SNP) | VAF 195/550 reads (35%) | catalogued as rs17845512, COSV99930966; called by muse, varscan2
- ISLR2 | c.1935C>T p.F645= | Silent (SNP) | VAF 185/409 reads (45%) | catalogued as rs754274817; called by muse, mutect2, varscan2
- SYDE1 | c.1017C>T p.G339= | Silent (SNP) | VAF 97/277 reads (35%) | catalogued as rs1476124907; called by muse, mutect2, varscan2
- GPR141BP | n.487A>T | RNA (SNP) | VAF 209/408 reads (51%) | called by muse, mutect2, varscan2
- OAZ3 | c.*17G>A | 3'UTR (SNP) | VAF 300/655 reads (46%) | called by muse, mutect2, varscan2
- PCSK7 | c.*1579G>A | 3'UTR (SNP) | VAF 27/153 reads (18%) | catalogued as rs375311757, COSV54062981; called by muse, mutect2, varscan2
- TAC4 | c.123+651C>T | Intron (SNP) | VAF 54/1610 reads (3%) | catalogued as rs1445115220; called by muse, mutect2
